Somatic mutation profile of tumor specimen BA2583D (aliquot aq-BA2583D) from BEATAML1.0 case 2175, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.6 years (29,441 days).
Specimen BA2583D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b28d971c-dab3-4c6c-878b-72c7e79058b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2638D (Solid Tissue Normal), aliquot aq-BA2638D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7d5875-76dd-45e9-9ba4-50061a855f0a

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1B | c.11144G>T p.C3715F | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67256724, COSV99069017; called by muse, mutect2
- VDAC2 | c.493del p.Q165Rfs*2 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as COSV100040975; called by mutect2, varscan2
- CD101 | c.1953C>A p.Y651* | Nonsense Mutation (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- CDHR3 | c.1258A>C p.N420H | Missense Mutation (SNP) | VAF 4/106 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2
- FAT2 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2
- HEPHL1 | c.2352G>C p.K784N | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX5 | c.1560C>A p.G520= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100979904; called by muse, mutect2
- IRF2BPL | c.1146G>T p.L382= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- BCAR3 | c.358-21542G>A | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as rs763904772; called by muse, mutect2, varscan2
- GCNT2 | c.925+43C>A | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SLC22A17 | n.1295G>T | RNA (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
